Somatic mutation profile of tumor specimen C3N-02425-01 (aliquot CPT0183250007) from CPTAC case C3N-02425, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 61.2 years (22,361 days).
Specimen C3N-02425-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62a71451-a2c5-495e-8ffd-d61b5c341543.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02425-71 (Blood Derived Normal), aliquot CPT0183310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e79b698-32ea-4f1b-b565-ce9881911d8f

The open-access MAF lists 281 somatic variants for this specimen: 201 protein-altering or splice-affecting, 44 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 44, Intron 17, Frame Shift Del 11, Nonsense Mutation 7, Splice Site 7, RNA 6, 3'UTR 6, Splice Region 5, 5'Flank 3, Frame Shift Ins 3, 5'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 132/616 reads (21%) | catalogued as rs753683126, COSV56803611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 301/538 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.1419T>A p.S473R | Missense Mutation (SNP) | VAF 65/316 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60914907; called by muse, mutect2, varscan2
- ACTR2 | c.738C>T p.L246= | Splice Region (SNP) | VAF 23/149 reads (15%) | catalogued as COSV53200383, COSV53202183; called by muse, mutect2
- ADAMTS18 | c.2583del p.K862Rfs*3 | Frame Shift Del (DEL) | VAF 140/398 reads (35%) | catalogued as COSV99273717; called by mutect2, pindel, varscan2
- ADAMTSL3 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs148020587, COSV54447515; called by muse, mutect2, varscan2
- ADCY2 | c.2764G>C p.D922H | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57878273; called by muse, mutect2, varscan2
- ADD2 | c.686A>G p.H229R | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs201811808; called by muse, mutect2, varscan2
- ANGPTL7 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 13/372 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs924321890, COSV63869151; called by muse, mutect2
- AXL | c.1915G>T p.D639Y (on ENST00000301178 / NM_021913.5; = p.D630Y on NM_001699.6) | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs776653494; called by muse, mutect2, varscan2
- CABIN1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 110/660 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs751228495; called by muse, mutect2, varscan2
- CCDC7 | c.910A>T p.K304* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as rs375535605; called by muse, mutect2, varscan2
- CCL4L2 | c.265T>C p.W89R (on ENST00000617405 / NM_001291475.2; = p.H85= on NM_001291471.2) | Missense Mutation (SNP) | VAF 227/1511 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs557066618; called by muse, mutect2, varscan2
- CCSER1 | c.2464C>G p.R822G | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.062); catalogued as COSV61411301; called by muse, mutect2, varscan2
- CFHR5 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.823); catalogued as COSV56825131, COSV56829246; called by muse, mutect2, varscan2
- CSMD3 | c.10704del p.M3570* (on ENST00000297405 / NM_001363185.1; = p.M3401* on NM_052900.3) | Frame Shift Del (DEL) | VAF 50/159 reads (31%) | catalogued as COSV52296881; called by mutect2, pindel, varscan2
- DCAF4L2 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 147/382 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV60476425; called by muse, mutect2, varscan2
- DKK1 | c.743A>G p.Q248R | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs370680630; called by muse, mutect2, varscan2
- EPHA3 | c.475del p.D159Tfs*4 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | catalogued as COSV60725108; called by mutect2, pindel, varscan2
- FCRL1 | c.1264G>C p.D422H | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV63825940; called by muse, mutect2, varscan2
- FGFR4 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200766146, COSV52802276; called by muse, mutect2, varscan2
- FMN1 | c.3164G>T p.R1055L (on ENST00000616417 / NM_001277313.2; = p.R832L on NM_001103184.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57933713; called by muse, mutect2, varscan2
- FREM2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as rs778212803; called by muse, mutect2, varscan2
- GABBR2 | c.2027G>A p.W676* | Nonsense Mutation (SNP) | VAF 213/403 reads (53%) | catalogued as COSV99412083; called by muse, mutect2, varscan2
- GALC | c.443-1G>T p.X148_splice | Splice Site (SNP) | VAF 78/260 reads (30%) | catalogued as CS162963; called by muse, mutect2, varscan2
- GFI1B | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 28/548 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201349915, COSV59744336; called by muse, mutect2
- HAGH | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs1254003788; called by muse, mutect2, varscan2
- HORMAD1 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV100463847; called by muse, varscan2
- IL9R | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 666/1276 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1399137075; called by muse, varscan2
- ING4 | c.424C>T p.R142C (on ENST00000396807 / NM_001127582.2; = p.R141C on NM_016162.4) | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1309633605; called by muse, mutect2, varscan2
- ITGB7 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 107/192 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as rs779111282, COSV99914126; called by muse, mutect2, varscan2
- KCNG2 | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 213/436 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1460624840; called by muse, mutect2, varscan2
- KCTD17 | c.961A>G p.I321V (on ENST00000403888 / NM_001282684.1; = p.I297V on NM_024681.3) | Missense Mutation (SNP) | VAF 151/444 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1206449781; called by muse, mutect2, varscan2
- KNDC1 | c.3517G>A p.G1173R | Missense Mutation (SNP) | VAF 110/279 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV58835060; called by muse, mutect2, varscan2
- MAP3K4 | c.4168G>T p.E1390* | Nonsense Mutation (SNP) | VAF 32/108 reads (30%) | catalogued as COSV62330502; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs939755831, COSV51719782; called by muse, mutect2, varscan2
- MBD1 | c.1331G>A p.G444D (on ENST00000269468 / NM_001323950.1; = p.G388D on NM_002384.2) | Missense Mutation (SNP) | VAF 232/423 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1232115248; called by muse, mutect2, varscan2
- MDGA2 | c.1046C>A p.S349Y (on ENST00000399232 / NM_001113498.2; = p.S51Y on NM_182830.4) | Missense Mutation (SNP) | VAF 134/399 reads (34%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.577); catalogued as rs749875771, COSV100636573, COSV62087276; called by muse, mutect2, varscan2
- NAP1L3 | c.959del p.K320Rfs*9 | Frame Shift Del (DEL) | VAF 72/122 reads (59%) | catalogued as COSV59077419; called by mutect2, pindel, varscan2
- NLRP13 | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV61620063; called by muse, mutect2, varscan2
- NLRP5 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV66767385; called by muse, mutect2, varscan2
- NOTCH3 | c.2236G>A p.G746S | Missense Mutation (SNP) | VAF 134/270 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as rs1481559244; called by muse, varscan2
- NOX3 | c.128C>G p.T43R | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV50158568; called by muse, mutect2, varscan2
- NUTM2G | c.439T>C p.C147R | Missense Mutation (SNP) | VAF 157/603 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.072); catalogued as rs770719572; called by muse, mutect2, varscan2
- OR14K1 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs968169473; called by muse, mutect2, varscan2
- OR8A1 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 115/319 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV52507837; called by muse, mutect2, varscan2
- PABPC1L | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 81/670 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764642979; called by muse, mutect2, varscan2
- PHGR1 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 72/298 reads (24%) | PolyPhen possibly damaging (0.81); catalogued as COSV99140896; called by muse, varscan2
- PHLDB1 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 159/478 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs1325781375; called by muse, mutect2, varscan2
- PKD2L1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.111); catalogued as rs145997401, COSV58394861; called by muse, mutect2, varscan2
- PLA2R1 | c.1759G>A p.G587R | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51775466; called by muse, mutect2, varscan2
- PPARGC1A | c.844C>A p.R282S | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV53523784; called by muse, mutect2, varscan2
- PPP1R3A | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1387114087, COSV52894368; called by muse, mutect2, varscan2
- PSG1 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as rs752061482, COSV54948371; called by muse, mutect2, varscan2
- PYHIN1 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs747505040; called by muse, varscan2
- RAB11FIP4 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1377826154, COSV57932127; called by muse, mutect2
- RD3L | c.169dup p.T57Nfs*22 | Frame Shift Ins (INS) | VAF 108/354 reads (31%) | catalogued as rs1566726304; called by mutect2, varscan2
- SIPA1L1 | c.2970G>T p.Q990H | Missense Mutation (SNP) | VAF 248/697 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100665590; called by muse, mutect2, varscan2
- SLC24A4 | c.1343del p.R448Pfs*28 | Frame Shift Del (DEL) | VAF 59/263 reads (22%) | catalogued as COSV54114434; called by mutect2, pindel, varscan2
- SLC26A7 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV52606675; called by muse, mutect2, varscan2
- SLC44A5 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV63774480; called by muse, mutect2, varscan2
- SLC5A11 | c.997C>G p.L333V | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61741432; called by muse, mutect2, varscan2
- SOHLH1 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 121/255 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs763275089, COSV53681321; called by muse, mutect2, varscan2
- SPICE1 | c.451A>C p.I151L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs754757010; called by muse, mutect2, varscan2
- SULT1A2 | c.691_693del p.E231del | In Frame Del (DEL) | VAF 120/650 reads (18%) | catalogued as rs1163536877; called by mutect2, pindel, varscan2
- TAS1R3 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 125/486 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV59566168; called by muse, mutect2, varscan2
- TRIM14 | c.823A>T p.T275S | Missense Mutation (SNP) | VAF 108/567 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.068); catalogued as rs747298622; called by muse, mutect2, varscan2
- TSNARE1 | c.834G>T p.L278F | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as COSV100210266; called by muse, mutect2, varscan2
- UNC13A | c.4097G>A p.C1366Y | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1568508127; called by muse, mutect2, varscan2
- USH2A | c.13400C>T p.P4467L | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56408907, COSV56431815; called by muse, mutect2, varscan2
- USP32 | c.269G>C p.G90A | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778462893; called by muse, mutect2, varscan2
- WDR11 | c.2971C>T p.R991W | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1489936094; called by muse, mutect2
- WWP1 | c.1123A>T p.T375S | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs769739686; called by muse, mutect2, varscan2
- ABCA9 | c.3878C>A p.A1293E | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRA1 | c.827G>C p.R276T | Missense Mutation (SNP) | VAF 140/297 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF18 | c.949G>T p.E317* (on ENST00000359920 / NM_001130955.2; = p.E213* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/173 reads (24%) | called by muse, mutect2, varscan2
- BTK | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- BTN3A3 | c.608C>A p.A203E | Missense Mutation (SNP) | VAF 243/441 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- C2orf16 | c.5549A>G p.E1850G | Missense Mutation (SNP) | VAF 13/346 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- C5AR2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 63/313 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- C5orf34 | c.352A>G p.M118V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMK2B | c.757C>A p.L253M | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAND1 | c.3024dup p.G1009Rfs*2 | Frame Shift Ins (INS) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- CCDC142 | c.1390-1G>A p.X464_splice (on ENST00000393965 / NM_001365575.2; = p.X457_splice on NM_032779.4) | Splice Site (SNP) | VAF 42/126 reads (33%) | called by muse, mutect2, varscan2
- CD163 | c.1589G>C p.G530A | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEACAM5 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CENPE | c.5862T>G p.I1954M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- CES3 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CFAP43 | c.2384C>A p.A795D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CHD2 | c.4660A>T p.M1554L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CHRD | c.2554G>A p.V852M | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CLVS1 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- CNGA3 | c.2012G>T p.G671V | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTN1 | c.1715del p.N572Mfs*4 | Frame Shift Del (DEL) | VAF 108/362 reads (30%) | called by mutect2, pindel, varscan2
- CNTRL | c.4668G>A p.M1556I | Missense Mutation (SNP) | VAF 127/225 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL15A1 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CSF3R | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 88/471 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- CSMD3 | c.5107G>T p.D1703Y (on ENST00000297405 / NM_001363185.1; = p.D1599Y on NM_052900.3) | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CT55 | c.425-1G>T p.X142_splice | Splice Site (SNP) | VAF 59/67 reads (88%) | called by muse, mutect2, varscan2
- DDX27 | c.1521-1G>T p.X507_splice | Splice Site (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2, varscan2
- DLGAP3 | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 96/436 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DUOX1 | c.4213A>C p.K1405Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EPDR1 | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ETS1 | c.1201A>G p.I401V | Missense Mutation (SNP) | VAF 143/422 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- EYS | c.2837T>C p.L946P | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAHD2B | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAHD2B | c.499G>C p.G167R | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM78B | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FBXO47 | c.647_648insT p.R216Sfs*5 | Frame Shift Ins (INS) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- FIP1L1 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FSCN3 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 117/456 reads (26%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GABPA | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GALT | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 224/373 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM7 | c.1052C>A p.T351K | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HCFC2 | c.2266A>T p.T756S | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- HCN4 | c.224C>A p.A75E | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPH | c.3391T>A p.W1131R (on ENST00000343002; = p.W864R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/254 reads (70%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- HERC2 | c.6203A>T p.Q2068L | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HHIP | c.2018T>G p.I673S | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HHLA1 | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HOXA2 | c.461A>T p.Q154L | Missense Mutation (SNP) | VAF 227/515 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXD3 | c.83T>A p.L28Q | Missense Mutation (SNP) | VAF 160/340 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HRG | c.1216C>G p.P406A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- HRH4 | c.1044G>C p.W348C | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HSF5 | c.829C>A p.H277N | Missense Mutation (SNP) | VAF 98/249 reads (39%) | SIFT tolerated (0.97); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HTR3D | c.62C>A p.T21K | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- HUS1B | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 68/111 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- IGLJ7 | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 77/295 reads (26%) | called by muse, mutect2, varscan2
- IRX3 | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 13/333 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- ITGA10 | c.2514C>G p.Y838* | Nonsense Mutation (SNP) | VAF 51/198 reads (26%) | called by muse, mutect2, varscan2
- KCTD7 | c.395A>T p.Y132F | Missense Mutation (SNP) | VAF 198/696 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- KCTD7 | c.557C>T p.S186L (on ENST00000275532; = p.I199= on NM_153033.5) | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- KLF17 | c.595A>C p.T199P | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- LAMC1 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 85/379 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- LAMC3 | c.4676A>G p.N1559S | Missense Mutation (SNP) | VAF 237/440 reads (54%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- LRP8 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- LRRC9 | c.2645G>A p.S882N | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEL2 | c.2383C>A p.Q795K | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MALRD1 | c.5322T>A p.G1774= | Splice Region (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- MED20 | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 84/426 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC5B | c.4369C>T p.P1457S | Missense Mutation (SNP) | VAF 105/173 reads (61%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH15 | c.5727G>T p.K1909N | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MYO7A | c.2027A>T p.Y676F | Missense Mutation (SNP) | VAF 154/487 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MYPOP | c.134del p.R45Lfs*3 | Frame Shift Del (DEL) | VAF 159/476 reads (33%) | called by mutect2, pindel, varscan2
- NDUFS1 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- NEK5 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- NES | c.4222del p.E1408Sfs*42 | Frame Shift Del (DEL) | VAF 81/398 reads (20%) | called by mutect2, pindel, varscan2
- NKX1-1 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NME8 | c.91+2T>A p.X31_splice | Splice Site (SNP) | VAF 146/335 reads (44%) | called by muse, mutect2, varscan2
- NR2F2 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- NRF1 | c.877del p.A293Pfs*5 | Frame Shift Del (DEL) | VAF 85/411 reads (21%) | called by mutect2, pindel*, varscan2
- NXF5 | n.603A>C | Splice Region (SNP) | VAF 65/290 reads (22%) | called by muse, mutect2, varscan2
- NXPE1 | c.1604T>A p.I535N (on ENST00000424269; = p.I393N on NM_152315.5) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OCSTAMP | c.307C>G p.R103G | Missense Mutation (SNP) | VAF 206/617 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10A5 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 141/254 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- OR10AG1 | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2
- OR52B6 | c.905T>A p.V302D | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR7A17 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- P2RY2 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- PAX4 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 363/874 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH15 | c.5057C>A p.P1686Q | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- PCDHGA2 | c.2004C>G p.I668M | Missense Mutation (SNP) | VAF 301/646 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PDS5A | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PHKA1 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 181/231 reads (78%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PKHD1L1 | c.4133A>T p.E1378V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.228); called by muse, varscan2
- PLPP5 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PNPLA7 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 69/386 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- PRDM10 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRELID1 | c.512-5G>T | Splice Region (SNP) | VAF 61/239 reads (26%) | called by muse, mutect2, varscan2
- PREX1 | c.2333G>T p.R778L | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRKCE | c.1279C>A p.L427I | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PRKCI | c.980+1G>A p.X327_splice | Splice Site (SNP) | VAF 25/125 reads (20%) | called by muse, mutect2, varscan2
- PSD | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 127/329 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTCHD3 | c.1762T>C p.F588L | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAG2 | c.1576T>C p.F526L | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RB1CC1 | c.449G>C p.W150S | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RGPD8 | c.2789G>T p.G930V | Missense Mutation (SNP) | VAF 260/881 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RIN3 | c.2776C>A p.L926M | Missense Mutation (SNP) | VAF 205/623 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, varscan2
- RTN4 | c.2822A>T p.N941I | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SCAF8 | c.505A>C p.N169H | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- SGIP1 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SHISA3 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC1A7 | c.397A>T p.M133L | Missense Mutation (SNP) | VAF 63/394 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC5A8 | c.1442A>C p.N481T | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLIT2 | c.1491T>A p.S497R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- SORBS1 | c.2018C>T p.T673I (on ENST00000361941 / NM_001034954.2; = p.T379I on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- SPTA1 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SRRM2 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 200/379 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLE1 | c.1643del p.G548Efs*23 | Frame Shift Del (DEL) | VAF 214/528 reads (41%) | called by mutect2, pindel, varscan2
- TOPBP1 | c.2299G>T p.G767C | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TRMT2A | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRNT1 | c.153_156del p.F52Sfs*7 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- TTC30B | c.122G>T p.S41I | Missense Mutation (SNP) | VAF 30/746 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2
- TTN | c.61372G>A p.A20458T (on ENST00000591111; = p.A13034T on NM_003319.4) | Missense Mutation (SNP) | VAF 117/583 reads (20%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.43961C>T p.A14654V (on ENST00000591111; = p.A7230V on NM_003319.4) | Missense Mutation (SNP) | VAF 42/170 reads (25%) | PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- VIT | c.372A>T p.L124F | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- VPS37D | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF382 | c.-14G>T | Splice Region (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2
- ZNF382 | c.-14+1G>T | Splice Site (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2
- ZNF438 | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZNF804A | c.1314G>C p.Q438H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ABRA | c.462C>T p.H154= | Silent (SNP) | VAF 109/325 reads (34%) | catalogued as rs546797793, COSV61733918; called by muse, mutect2, varscan2
- ACTR1B | c.285C>A p.S95= | Silent (SNP) | VAF 63/303 reads (21%) | catalogued as rs1251765447; called by muse, mutect2, varscan2
- APOA4 | c.1080G>A p.E360= | Silent (SNP) | VAF 236/689 reads (34%) | catalogued as COSV63360415; called by muse, mutect2, varscan2
- ARSK | c.9G>T p.L3= | Silent (SNP) | VAF 264/495 reads (53%) | catalogued as COSV62453242; called by muse, mutect2, varscan2
- CEP250 | c.5787G>T p.L1929= | Silent (SNP) | VAF 215/468 reads (46%) | called by muse, mutect2, varscan2
- DDI2 | c.822G>A p.V274= | Silent (SNP) | VAF 49/296 reads (17%) | catalogued as rs1157499212; called by muse, mutect2, varscan2
- DDO | c.465G>A p.K155= (on ENST00000368924 / NM_001368172.1; = p.K96= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV64470707; called by muse, mutect2
- DNAH5 | c.2073T>C p.G691= | Silent (SNP) | VAF 38/208 reads (18%) | catalogued as rs1300434566; called by muse, mutect2, varscan2
- DPP6 | c.1392G>A p.T464= (on ENST00000377770 / NM_001364500.2; = p.T402= on NM_001936.5) | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as rs759587439, COSV59629369; called by muse, mutect2
- EP400 | c.3426C>G p.L1142= | Silent (SNP) | VAF 63/168 reads (38%) | catalogued as rs981988310, COSV57769392; called by muse, mutect2, varscan2
- EVI2B | c.309C>G p.A103= | Silent (SNP) | VAF 310/446 reads (70%) | called by muse, mutect2, varscan2
- FGF2 | c.441G>A p.E147= | Silent (SNP) | VAF 73/369 reads (20%) | called by muse, mutect2, varscan2
- FHIT | c.120G>T p.P40= | Silent (SNP) | VAF 74/136 reads (54%) | called by muse, mutect2, varscan2
- FMN2 | c.4323G>C p.L1441= | Silent (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- HORMAD1 | c.216C>T p.C72= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- IFNL1 | c.540C>T p.D180= | Silent (SNP) | VAF 74/254 reads (29%) | called by muse, mutect2, varscan2
- IGLJ7 | c.18C>T p.F6= | Silent (SNP) | VAF 76/293 reads (26%) | catalogued as rs766110086; called by muse, mutect2, varscan2
- KANK4 | c.531G>A p.E177= | Silent (SNP) | VAF 56/278 reads (20%) | catalogued as COSV62985759; called by muse, mutect2, varscan2
- LAMTOR4 | c.174C>T p.G58= | Silent (SNP) | VAF 181/695 reads (26%) | called by muse, mutect2, varscan2
- LCTL | c.156G>A p.T52= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as rs779191267; called by muse, mutect2, varscan2
- LEMD2 | c.1507C>A p.R503= | Silent (SNP) | VAF 49/81 reads (60%) | catalogued as rs771774908, COSV53394689; called by muse, mutect2, varscan2
- LMNB2 | c.1179G>A p.K393= | Silent (SNP) | VAF 257/493 reads (52%) | called by muse, mutect2, varscan2
- MCM2 | c.339A>G p.A113= | Silent (SNP) | VAF 83/422 reads (20%) | called by muse, mutect2, varscan2
- MORF4L2 | c.258A>T p.G86= | Silent (SNP) | VAF 84/112 reads (75%) | called by muse, mutect2, varscan2
- MYO16 | c.495T>C p.Y165= | Silent (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- MYO18B | c.5412C>T p.L1804= | Silent (SNP) | VAF 42/214 reads (20%) | called by muse, mutect2, varscan2
- NBAS | c.3801G>A p.E1267= | Silent (SNP) | VAF 131/419 reads (31%) | called by muse, mutect2, varscan2
- OR4C16 | c.675C>T p.N225= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs770119710; called by muse, mutect2, varscan2
- OR51Q1 | c.90C>G p.S30= | Silent (SNP) | VAF 82/140 reads (59%) | catalogued as COSV56179957; called by muse, mutect2, varscan2
- OR6F1 | c.78T>C p.S26= | Silent (SNP) | VAF 47/113 reads (42%) | called by muse, mutect2, varscan2
- PAN3 | c.735G>C p.P245= | Silent (SNP) | VAF 50/85 reads (59%) | called by muse, mutect2, varscan2
- PCDHA7 | c.66A>C p.A22= | Silent (SNP) | VAF 60/111 reads (54%) | called by muse, mutect2, varscan2
- PCNX2 | c.1677C>T p.S559= | Silent (SNP) | VAF 35/157 reads (22%) | catalogued as rs764217891, COSV50822613; called by muse, mutect2, varscan2
- PIEZO2 | c.1095G>A p.G365= | Silent (SNP) | VAF 79/135 reads (59%) | called by muse, mutect2, varscan2
- PTPRU | c.3591C>T p.I1197= | Silent (SNP) | VAF 106/257 reads (41%) | catalogued as rs777689742, COSV60521998; called by muse, mutect2, varscan2
- SHISA3 | c.204G>T p.A68= | Silent (SNP) | VAF 43/313 reads (14%) | called by muse, mutect2, varscan2
- SLC4A1 | c.1056C>T p.A352= | Silent (SNP) | VAF 195/392 reads (50%) | called by muse, mutect2, varscan2
- SMG1 | c.4695A>T p.I1565= | Silent (SNP) | VAF 24/119 reads (20%) | called by muse, mutect2, varscan2
- SRGAP2 | c.2148G>T p.V716= (on ENST00000624873 / NM_001170637.4; = p.V717= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 45/254 reads (18%) | called by muse, mutect2, varscan2
- TMEM191C | c.279G>C p.L93= | Silent (SNP) | VAF 117/372 reads (31%) | called by muse, mutect2, varscan2
- TPH2 | c.630G>T p.V210= | Silent (SNP) | VAF 105/309 reads (34%) | called by muse, mutect2, varscan2
- YOD1 | c.762A>T p.G254= | Silent (SNP) | VAF 87/186 reads (47%) | called by muse, mutect2, varscan2
- ZNF469 | c.777C>T p.P259= | Silent (SNP) | VAF 110/486 reads (23%) | called by muse, mutect2, varscan2
- ZNF763 | c.213C>T p.V71= (on ENST00000358987 / NM_001367172.2; = p.V74= on NM_001012753.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- AL590867.2 | n.366C>A | RNA (SNP) | VAF 125/269 reads (46%) | called by muse, mutect2, varscan2
- ALG3 | c.*15C>T | 3'UTR (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.*184G>A | 3'UTR (SNP) | VAF 59/288 reads (20%) | called by muse, mutect2, varscan2
- ATG4B | c.957+37G>T | Intron (SNP) | VAF 79/292 reads (27%) | called by muse, mutect2, varscan2
- C14orf132 | c.-1C>T | 5'UTR (SNP) | VAF 55/179 reads (31%) | called by muse, mutect2, varscan2
- C1QBP | c.-10C>G | 5'UTR (SNP) | VAF 122/461 reads (26%) | called by muse, mutect2, varscan2
- C22orf15 | c.*28C>T | 3'UTR (SNP) | VAF 24/102 reads (24%) | called by muse, varscan2
- C22orf15 | c.*36del | 3'UTR (DEL) | VAF 16/94 reads (17%) | catalogued as rs1443768387; called by pindel, varscan2
- CROCC2 | c.4557+634C>T | Intron (SNP) | VAF 88/293 reads (30%) | called by muse, mutect2, varscan2
- FAM183BP | n.1075G>T | RNA (SNP) | VAF 94/454 reads (21%) | called by muse, mutect2, varscan2
- GALNT13 | c.1396-1005C>A | Intron (SNP) | VAF 29/64 reads (45%) | catalogued as rs1200485513; called by muse, mutect2, varscan2
- GALNT13 | c.1531-3800T>C | Intron (SNP) | VAF 49/77 reads (64%) | called by muse, mutect2, varscan2
- GP6 | c.665-20A>T | Intron (SNP) | VAF 108/250 reads (43%) | called by muse, mutect2, varscan2
- INCA1 | c.-15C>T | 5'UTR (SNP) | VAF 92/203 reads (45%) | called by muse, mutect2, varscan2
- KCNH2 | c.1945+39G>T | Intron (SNP) | VAF 100/318 reads (31%) | called by muse, mutect2, varscan2
- LINC01193 | n.1432C>T | RNA (SNP) | VAF 51/619 reads (8%) | called by muse, mutect2
- LMX1B | c.886+14G>T | Intron (SNP) | VAF 183/328 reads (56%) | catalogued as rs762072087; called by muse, mutect2, varscan2
- LRR1 | chr14:49598559 A>T | 5'Flank (SNP) | VAF 211/595 reads (35%) | called by muse, mutect2, varscan2
- MAGEA4 | chrX:151912466 C>G | 5'Flank (SNP) | VAF 132/173 reads (76%) | called by muse, mutect2, varscan2
- MKRN2 | chr3:12585089 G>A | 3'Flank (SNP) | VAF 64/192 reads (33%) | catalogued as rs765872629; called by muse, mutect2, varscan2
- MMP16 | c.1222+5097C>A | Intron (SNP) | VAF 35/146 reads (24%) | called by muse, mutect2
- OGFOD3 | c.824-1898A>G | Intron (SNP) | VAF 100/215 reads (47%) | called by muse, mutect2, varscan2
- OR4C4P | n.156C>A | RNA (SNP) | VAF 49/155 reads (32%) | called by muse, mutect2, varscan2
- PDIA3P1 | n.1635A>C | RNA (SNP) | VAF 57/253 reads (23%) | called by muse, mutect2, varscan2
- PNPO | c.138+51C>G | Intron (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- RBFOX1 | c.996-15688del | Intron (DEL) | VAF 28/125 reads (22%) | catalogued as COSV60974478; called by mutect2, pindel, varscan2
- RUSC1 | c.1358-407G>C | Intron (SNP) | VAF 40/259 reads (15%) | called by muse, mutect2, varscan2
- SFSWAP | c.2409-1295C>A | Intron (SNP) | VAF 134/389 reads (34%) | called by muse, mutect2, varscan2
- SLC25A40 | c.*61G>C | 3'UTR (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- SNX18 | c.1774+47A>G | Intron (SNP) | VAF 24/82 reads (29%) | catalogued as rs1233025285; called by muse, mutect2, varscan2
- SPG7 | c.1643-39G>C | Intron (SNP) | VAF 187/426 reads (44%) | called by muse, mutect2, varscan2
- SSPOP | n.4392G>A | RNA (SNP) | VAF 258/847 reads (30%) | catalogued as rs746702639; called by muse, mutect2, varscan2
- TNS3 | c.*88A>C | 3'UTR (SNP) | VAF 41/183 reads (22%) | called by muse, mutect2, varscan2
- TRPA1 | c.3150-24C>T | Intron (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- ZBTB17 | c.1371+48G>A | Intron (SNP) | VAF 52/198 reads (26%) | catalogued as rs891528921; called by muse, mutect2, varscan2
- ZNF467 | chr7:149777825 G>A | 5'Flank (SNP) | VAF 105/221 reads (48%) | catalogued as rs748568156; called by muse, mutect2, varscan2
